Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A05J, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A05J-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: Lymph node, obturator, right; excision
- 2: Lymph node, common iliac, right; excision
- 3: Lymph node, para-aortic, right; excision
- 4: Lymph node, common iliac, left; excision
- 5: Omentum; omentectomy
- 6: Uterus, cervix, bilateral fallopian tubes and ovaries; total hysterectomy with bilateral salpingo-oophorectomy
- 7: Lymph node, external iliac, left; excision
- 8: Lymph node, obturator, left; excision
- 9: Lymph node, external iliac, right; excision

ICD-0-3

adenocarcinoma, serous, NOS 8441/3

Site: endometrium c54.1

5/2/11

DIAGNOSIS:

1. Lymph node, obturator, right; excision:
Four benign lymph nodes (0/4)
2. Lymph node, common iliac, right; excision:
One benign lymph node (0/1)
3. Lymph node, para-aortic, right; excision:
One benign lymph node (0/1)
4. Lymph node, common iliac, left; excision:
One benign lymph node (0/1)
5. Omentum; omentectomy:
Benign mature adipose tissue
6. Uterus, cervix, bilateral fallopian tubes and ovaries; total hysterectomy with bilateral salpingo-oophorectomy:
Tumor Type:
Adenocarcinoma, serous (papillary serous) type
High grade
Myometrial Invasion:
Not identified
Endocervical Invasion:
Mucosa and stroma

** Continued on next page **

[page 2 of 2]
Depth of cervical stromal invasion:

Measures 1mm

Cervical wall thickness measures 16mm in the area of maximum tumor

invasion

Lymphovascular invasion:

Not identified

Endometrium:

Exhibits atrophy

Myometrium:

Exhibits one leiomyoma

Adnexa:

Unremarkable

Comment: The previous material was reviewed, which was diagnostic for
carcinosarcoma [REDACTED]. Sarcomatous elements are not identified in the
current material.

7. Lymph node, external iliac, left; excision:
Two benign lymph nodes (0/2)
8. Lymph node, obturator, left; excision:
Two benign lymph nodes (0/2)
9. Lymph node, external iliac, right; excision:
Four benign lymph nodes (0/4)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

Source: NCI Genomic Data Commons file 59f1f60c-14e5-4098-8a9b-f60c62f294e5 (TCGA-AP-A05J.C6426DA0-86C5-49CC-9983-A0002DA0D4F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).